Somatic mutation profile of tumor specimen HCM-CSHL-0064-C18-86A (aliquot HCM-CSHL-0064-C18-86A-01D-A78L-36) from HCMI case HCM-CSHL-0064-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 75.4 years (27,552 days).
Specimen HCM-CSHL-0064-C18-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f384d1b-0782-4fd4-acf9-3577c33b6674.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0064-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0064-C18-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4bfd2bb-5e8e-4336-b5ff-e439ce4815e0

The open-access MAF lists 348 somatic variants for this specimen: 226 protein-altering or splice-affecting, 75 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 75, Intron 23, Nonsense Mutation 22, 5'UTR 12, Frame Shift Del 6, Splice Site 6, RNA 5, Splice Region 3, Frame Shift Ins 3, 5'Flank 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 168/169 reads (99%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACER2 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.591); catalogued as COSV61820758; called by muse, mutect2, varscan2
- AGBL1 | c.2404C>T p.R802* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as rs773153038, COSV66858794; called by muse, mutect2, varscan2
- ALK | c.1562T>A p.L521H | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV66568222; called by muse, mutect2, varscan2
- ANKRD24 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 84/353 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs866437534; called by muse, mutect2, varscan2
- APC | c.3404A>T p.Y1135F | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.956); catalogued as CD084033; called by muse, varscan2
- APEH | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 71/256 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs758904075; called by muse, mutect2, varscan2
- ASPG | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 207/207 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1170649369; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs569799893; called by muse, mutect2, varscan2
- C2CD2L | c.125C>G p.A42G | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1040454427; called by muse, mutect2, varscan2
- CCER1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs868224869; called by muse, mutect2, varscan2
- CCKBR | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as rs1181500642, COSV100582881; called by muse, mutect2, varscan2
- CEP295 | c.6727G>C p.D2243H | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as COSV57344855; called by muse, mutect2, varscan2
- CHMP4B | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 51/503 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99459768; called by muse, mutect2, varscan2
- CLCN1 | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 289/397 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs763760683; called by muse, mutect2, varscan2
- CNGB1 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 98/613 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs764107600, COSV51905464; called by muse, mutect2, varscan2
- COL12A1 | c.7869C>A p.N2623K | Missense Mutation (SNP) | VAF 109/109 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201337277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRMP1 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs370759908; called by muse, mutect2, varscan2
- DNAJA1 | c.439G>C p.V147L | Missense Mutation (SNP) | VAF 143/272 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV99044021; called by muse, mutect2, varscan2
- DNAJC13 | c.6344G>A p.R2115Q | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.421); catalogued as rs770715465, CM141864, COSV53450154; called by muse, mutect2, varscan2
- DTNB | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs777533811; called by muse, mutect2, varscan2
- ELAVL2 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 84/482 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.093); catalogued as rs1188175446, COSV99805698; called by muse, mutect2, varscan2
- EPN3 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746697052, COSV52141953; called by muse, mutect2, varscan2
- FAM83B | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 156/264 reads (59%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1465244268; called by muse, mutect2, varscan2
- FCRL5 | c.2561G>T p.G854V | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV99052721; called by muse, mutect2, varscan2
- FOXO1 | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769622051; called by muse, mutect2, varscan2
- GALNT17 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 84/349 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV61149754; called by muse, mutect2, varscan2
- GJD4 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as rs778114104, COSV58702441; called by muse, mutect2, varscan2
- GOLGA4 | c.6347C>T p.T2116M | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs780800757; called by muse, mutect2, varscan2
- GRM6 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 145/287 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV51451186; called by muse, mutect2, varscan2
- HLA-F | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 122/200 reads (61%) | catalogued as rs747319246; called by muse, mutect2, varscan2
- IKZF1 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 90/451 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.148); catalogued as COSV100497807, COSV58784077; called by muse, mutect2, varscan2
- INSL3 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs202136873; called by muse, mutect2, varscan2
- KAT2B | c.306C>T p.A102= | Splice Region (SNP) | VAF 25/175 reads (14%) | catalogued as rs894033666, COSV55431080; called by muse, mutect2, varscan2
- KCNA1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 19/527 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66838104; called by muse, mutect2
- KCNT2 | c.686T>A p.L229H | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99652280; called by muse, mutect2, varscan2
- KLC2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 90/180 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs765203566, COSV100270558; called by muse, mutect2, varscan2
- KLK6 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 137/185 reads (74%) | catalogued as rs377282019, COSV100037783; called by muse, mutect2, varscan2
- KMT2B | c.4847C>T p.A1616V | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55866983, COSV99720244; called by muse, mutect2, varscan2
- LTN1 | c.2467A>T p.I823F | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs1466784065; called by muse, mutect2, varscan2
- MCC | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 252/254 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs764285047; called by muse, mutect2, varscan2
- MED12L | c.4192G>A p.G1398R | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV56397329; called by mutect2, varscan2
- MROH5 | c.2566C>T p.R856* | Nonsense Mutation (SNP) | VAF 41/316 reads (13%) | catalogued as rs549578686, COSV101436180; called by muse, varscan2
- MROH9 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as rs748891805, COSV63010002; called by muse, mutect2, varscan2
- MS4A18 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs534337923, COSV67517736; called by muse, mutect2, varscan2
- NPIPB15 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 134/1399 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.78); catalogued as rs761593756, COSV70437899; called by muse, mutect2
- OFD1 | c.412+8C>G | Splice Region (SNP) | VAF 50/122 reads (41%) | catalogued as COSV60794453; called by muse, mutect2, varscan2
- OR4D9 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 84/164 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs535085659, COSV61434513; called by muse, mutect2, varscan2
- OR5D18 | c.545T>C p.F182S | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs1376035809; called by muse, mutect2, varscan2
- OTOF | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 110/437 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs1245016113, COSV55498199, COSV55502880; called by muse, mutect2, varscan2
- PCDHB7 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 167/838 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.458); catalogued as rs148889209; called by muse, mutect2, varscan2
- PCDHB9 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 177/414 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs782349216; called by muse, mutect2, varscan2
- PDE1C | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs775393302, COSV58502926; called by muse, mutect2, varscan2
- PDILT | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 131/166 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs765889720; called by muse, mutect2, varscan2
- PKHD1 | c.9120C>A p.D3040E | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV61890691; called by muse, mutect2, varscan2
- POM121L12 | c.755G>A p.W252* | Nonsense Mutation (SNP) | VAF 37/311 reads (12%) | catalogued as COSV68694686; called by muse, mutect2, varscan2
- PPP1R13L | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs759404256; called by muse, mutect2, varscan2
- PRAME | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs201064885; called by muse, mutect2, varscan2
- PROCR | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 112/874 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs774060495; called by muse, mutect2, varscan2
- PRSS56 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1263692375; called by muse, mutect2, varscan2
- QRICH2 | c.4136G>A p.R1379H | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772000651, COSV53154869, COSV53158477; called by muse, mutect2, varscan2
- RAB3D | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs200374153; called by muse, mutect2, varscan2
- RAP1GDS1 | c.544A>T p.I182F (on ENST00000408927 / NM_001100427.2; = p.I183F on NM_021159.5) | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV52786764; called by muse, mutect2, varscan2
- RBM20 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 129/165 reads (78%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs923358109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs370474035; called by muse, mutect2, varscan2
- SLC12A5 | c.2478A>C p.L826F (on ENST00000454036 / NM_001134771.2; = p.L803F on NM_020708.5) | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.359); catalogued as rs1304975707; called by muse, mutect2
- SLC15A2 | c.1761+2T>C p.X587_splice | Splice Site (SNP) | VAF 53/192 reads (28%) | catalogued as rs1175374313; called by muse, mutect2, varscan2
- SLC46A3 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV57180752; called by muse, mutect2
- SLC4A3 | c.538G>T p.G180W | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV99813087; called by muse, varscan2
- SLC5A11 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 109/633 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1567658010, COSV61744060; called by muse, mutect2, varscan2
- SLC6A5 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 86/354 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV54225086; called by muse, mutect2, varscan2
- SLITRK1 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 29/209 reads (14%) | catalogued as rs1041104860, COSV65674040, COSV65675357; called by muse, mutect2, varscan2
- SYTL3 | c.1034C>T p.P345L (on ENST00000611299 / NM_001242394.1; = p.P277L on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774253415, COSV51908430, COSV99791835; called by muse, mutect2, varscan2
- TBC1D9 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778160381; called by muse, mutect2, varscan2
- TELO2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs1281622827; called by muse, mutect2, varscan2
- TERT | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 20/730 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1414081; called by muse, mutect2
- TM9SF2 | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225294102; called by muse, mutect2, varscan2
- TMEM132A | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.809); catalogued as rs753135679, COSV50013072; called by muse, mutect2, varscan2
- TSPYL4 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV60305651; called by muse, mutect2, varscan2
- TXNDC12 | c.44T>A p.F15Y | Missense Mutation (SNP) | VAF 133/308 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as rs766482803; called by muse, mutect2, varscan2
- UBA7 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757115951; called by muse, mutect2, varscan2
- UGT2B7 | c.1190C>G p.A397G | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV59442867; called by muse, mutect2, varscan2
- UNC80 | c.422G>T p.W141L | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.106); catalogued as COSV55904593; called by muse, mutect2, varscan2
- VWCE | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs541004294, COSV57113297; called by muse, mutect2, varscan2
- VXN | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757732888, COSV59685450; called by muse, mutect2, varscan2
- WIZ | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765294195; called by muse, mutect2, varscan2
- WRNIP1 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.179); catalogued as rs750497757; called by muse, mutect2, varscan2
- ZC3H4 | c.3868G>A p.V1290I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1288669302; called by muse, mutect2, varscan2
- ZFP64 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 213/1200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749217635; called by muse, mutect2, varscan2
- ZNF311 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 120/314 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs1156904558; called by muse, mutect2, varscan2
- ABCA2 | c.4778A>T p.E1593V (on ENST00000614293; = p.E1563V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- AC100868.1 | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 68/497 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ACACA | c.5451C>G p.Y1817* | Nonsense Mutation (SNP) | VAF 76/144 reads (53%) | called by muse, mutect2, varscan2
- ADCK5 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 11/328 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.17); called by muse, mutect2
- ALDH1L1 | c.1737G>T p.M579I | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2
- ANAPC1 | c.2936G>T p.G979V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- ANKFN1 | c.589G>C p.G197R | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- AP3S1 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ARFGEF2 | c.2635G>T p.A879S | Missense Mutation (SNP) | VAF 80/759 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ARHGAP15 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ARHGAP32 | c.5508G>A p.M1836I (on ENST00000310343 / NM_001378025.1; = p.M1487I on NM_014715.4) | Missense Mutation (SNP) | VAF 69/349 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF6 | c.1004G>A p.C335Y | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID5A | c.230A>C p.E77A | Missense Mutation (SNP) | VAF 85/160 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ARMC1 | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ARNTL2 | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ARR3 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- ATP11B | c.2642_2643insG p.Y881* | Nonsense Mutation (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel
- C20orf96 | c.307A>T p.T103S (on ENST00000360321 / NM_153269.3; = p.T102S on NM_080571.1) | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C3orf84 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 74/350 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CASTOR2 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 11/305 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- CC2D2B | c.131A>T p.K44M (on ENST00000646931 / NM_001349008.3; = p.K36M on NM_001130446.3) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CCDC168 | c.13066G>C p.D4356H | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CCDC168 | c.10917T>G p.N3639K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- CCDC91 | c.301T>A p.S101T | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC91 | c.302C>A p.S101* | Nonsense Mutation (SNP) | VAF 34/144 reads (24%) | called by muse, mutect2, varscan2
- CCL23 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CDC14A | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 43/200 reads (22%) | called by muse, mutect2, varscan2
- CEP128 | c.1383C>A p.Y461* | Nonsense Mutation (SNP) | VAF 173/261 reads (66%) | called by muse, mutect2, varscan2
- CFAP94 | c.1743_1753del p.Y581* (on ENST00000320267 / NM_001352064.2; = p.Y587* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (DEL) | VAF 20/129 reads (16%) | called by mutect2, pindel, varscan2
- CMYA5 | c.5572A>T p.R1858* | Nonsense Mutation (SNP) | VAF 50/178 reads (28%) | called by muse, mutect2, varscan2
- COL25A1 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- COL6A3 | c.6625A>T p.K2209* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- COPS8 | c.198+1del p.X66_splice | Splice Site (DEL) | VAF 17/98 reads (17%) | called by mutect2, pindel*, varscan2
- COX19 | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CPO | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CTH | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 91/444 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH3 | c.7517A>G p.N2506S | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- DNAH9 | c.4407A>G p.I1469M | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- DNAJB7 | c.881_882insC p.K294Nfs*5 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel
- DOCK2 | c.1475C>G p.T492R | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- DOCK8 | c.2752G>T p.E918* | Nonsense Mutation (SNP) | VAF 74/441 reads (17%) | called by muse, mutect2, varscan2
- DPY19L3 | c.878A>G p.Q293R | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DSCC1 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DUSP1 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDC3 | c.1192+6C>G | Splice Region (SNP) | VAF 76/215 reads (35%) | called by muse, mutect2, varscan2
- ELMO2 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 39/494 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.024); called by muse, mutect2
- ENAM | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ERBIN | c.2650T>G p.Y884D | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- FAM20B | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- FAM234B | c.1741A>T p.S581C | Missense Mutation (SNP) | VAF 60/287 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FKBP6 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 37/670 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- FNBP4 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 133/262 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FRAS1 | c.8927_8928del p.S2976Ffs*21 | Frame Shift Del (DEL) | VAF 48/128 reads (38%) | called by pindel, varscan2
- FRMD3 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRYL | c.989T>G p.L330* | Nonsense Mutation (SNP) | VAF 68/113 reads (60%) | called by muse, mutect2, varscan2
- GP6 | c.998A>C p.H333P | Missense Mutation (SNP) | VAF 127/595 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR150 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GSG1L | c.890A>T p.Y297F (on ENST00000447459 / NM_001109763.2; = p.Y142F on NM_144675.2) | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- HIP1 | c.2965G>C p.E989Q | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXD10 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, varscan2
- IDO1 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 66/316 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH7 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- KCNT2 | c.175+2T>A p.X59_splice | Splice Site (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- KIAA1549 | c.4937C>G p.P1646R | Missense Mutation (SNP) | VAF 81/460 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KIF11 | c.585A>G p.I195M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KIF13A | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 110/110 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- KIF2B | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIF4A | c.153C>A p.Y51* | Nonsense Mutation (SNP) | VAF 8/191 reads (4%) | called by muse, mutect2
- LAMB3 | c.2041G>C p.D681H | Missense Mutation (SNP) | VAF 80/357 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LAT2 | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCA5 | c.559A>T p.K187* | Nonsense Mutation (SNP) | VAF 55/389 reads (14%) | called by muse, mutect2, varscan2
- LCP2 | c.289A>T p.S97C | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIPI | c.657A>T p.L219F | Missense Mutation (SNP) | VAF 59/473 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRD1 | c.2282A>C p.K761T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MCOLN1 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MIIP | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MLF2 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MMP12 | c.108C>G p.Y36* | Nonsense Mutation (SNP) | VAF 30/139 reads (22%) | called by muse, mutect2, varscan2
- MRPL3 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH10 | c.3858+1G>A p.X1286_splice | Splice Site (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2
- NARS1 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NFKBIL1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 114/674 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NPIPB15 | c.767T>G p.I256R | Missense Mutation (SNP) | VAF 133/1390 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.893); called by muse, mutect2
- OR2T27 | c.393C>G p.H131Q | Missense Mutation (SNP) | VAF 67/375 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR7A17 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- OTX1 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAK1IP1 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 98/158 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH11X | c.3577A>G p.I1193V | Missense Mutation (SNP) | VAF 607/609 reads (100%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCSK9 | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDPR | c.2563C>G p.L855V | Missense Mutation (SNP) | VAF 58/433 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- PLA2G7 | c.430T>G p.Y144D | Missense Mutation (SNP) | VAF 163/484 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLG | c.2296T>A p.C766S | Missense Mutation (SNP) | VAF 82/465 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRRT3 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PTK2 | c.789+2T>A p.X263_splice | Splice Site (SNP) | VAF 57/414 reads (14%) | called by muse, mutect2, varscan2
- PTPRC | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.162); called by muse, mutect2
- RANBP3 | c.776C>G p.A259G (on ENST00000340578 / NM_007322.3; = p.A254G on NM_003624.3) | Missense Mutation (SNP) | VAF 67/100 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- RANBP6 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- RBFOX2 | c.510A>C p.Q170H (on ENST00000438146 / NM_001349995.2; = p.Q100H on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- RILP | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- RPN2 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 90/1247 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- RRAD | c.191_203del p.G64Afs*65 | Frame Shift Del (DEL) | VAF 34/194 reads (18%) | called by mutect2, pindel
- SAMD9L | c.2916A>G p.I972M | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- SH3D19 | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC24A5 | c.584T>A p.V195D | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC35D3 | c.490G>C p.A164P | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLIT2 | c.458T>A p.I153K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- SLIT2 | c.463_464insC p.N155Tfs*13 | Frame Shift Ins (INS) | VAF 28/96 reads (29%) | called by pindel, varscan2
- SPAG16 | c.1262G>A p.W421* | Nonsense Mutation (SNP) | VAF 83/163 reads (51%) | called by muse, mutect2, varscan2
- SPEF2 | c.3598G>C p.D1200H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SRM | c.221_224del p.R74Tfs*8 | Frame Shift Del (DEL) | VAF 43/100 reads (43%) | called by mutect2, pindel, varscan2
- STK17A | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STS | c.892A>T p.S298C | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SVOP | c.946del p.T316Qfs*19 | Frame Shift Del (DEL) | VAF 54/214 reads (25%) | called by mutect2, pindel, varscan2
- TAAR2 | c.337C>T p.L113F (on ENST00000367931 / NM_001033080.1; = p.L68F on NM_014626.3) | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBC1D19 | c.1507-1G>A p.X503_splice | Splice Site (SNP) | VAF 46/119 reads (39%) | called by muse, mutect2, varscan2
- TESK2 | c.1492_1494del p.P498del | In Frame Del (DEL) | VAF 47/242 reads (19%) | called by pindel, varscan2
- THADA | c.1821T>A p.H607Q | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TMTC1 | c.1249A>T p.S417C (on ENST00000539277 / NM_001193451.2; = p.S309C on NM_175861.3) | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRERF1 | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TUBGCP2 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 94/126 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBR5 | c.1502A>G p.Q501R | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2
- USP25 | c.2012C>G p.T671S | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); called by muse, mutect2
- VEGFC | c.1040G>T p.C347F | Missense Mutation (SNP) | VAF 102/102 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- VPS13A | c.6548T>C p.F2183S | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- VWA5B2 | c.3149G>C p.S1050T | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VWA8 | c.923T>A p.L308H | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- WDR24 | c.372G>C p.K124N (on ENST00000248142; = p.K62N on NM_032259.4) | Missense Mutation (SNP) | VAF 94/557 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- XCL1 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZDBF2 | c.1437T>G p.H479Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF268 | c.2362del p.A788Lfs*8 | Frame Shift Del (DEL) | VAF 22/113 reads (19%) | called by mutect2, pindel, varscan2
- ZNF320 | c.1435_1436insAG p.S479Kfs*3 | Frame Shift Ins (INS) | VAF 20/134 reads (15%) | called by mutect2, varscan2*
- ZNF320 | c.1433_1434del p.F478* | Frame Shift Del (DEL) | VAF 23/144 reads (16%) | called by mutect2, varscan2*
- ZNF512B | c.1751T>C p.L584P | Missense Mutation (SNP) | VAF 432/823 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNHIT6 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ZSWIM1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 70/752 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- ABCA13 | c.7425T>G p.T2475= | Silent (SNP) | VAF 28/154 reads (18%) | called by muse, mutect2, varscan2
- AC008397.2 | c.1455A>C p.R485= | Silent (SNP) | VAF 34/135 reads (25%) | called by muse, mutect2, varscan2
- ACTRT2 | c.540C>A p.T180= | Silent (SNP) | VAF 71/226 reads (31%) | catalogued as COSV65759067; called by muse, mutect2, varscan2
- ADAMTS5 | c.136C>A p.R46= | Silent (SNP) | VAF 86/310 reads (28%) | called by muse, mutect2, varscan2
- ANKRD66 | c.258T>G p.G86= | Silent (SNP) | VAF 23/165 reads (14%) | called by muse, mutect2, varscan2
- AP2M1 | c.591G>A p.S197= | Silent (SNP) | VAF 64/517 reads (12%) | catalogued as rs771453400, COSV53047759, COSV53048423; called by muse, mutect2, varscan2
- BACH2 | c.1572T>G p.S524= | Silent (SNP) | VAF 63/153 reads (41%) | called by muse, mutect2, varscan2
- BTBD11 | c.1266A>C p.V422= | Silent (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- CA13 | c.87A>G p.Q29= | Silent (SNP) | VAF 35/237 reads (15%) | called by muse, mutect2, varscan2
- CEP290 | c.4776T>A p.A1592= | Silent (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- CFAP69 | c.678T>A p.T226= | Silent (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- COL11A1 | c.2391C>T p.D797= | Silent (SNP) | VAF 48/216 reads (22%) | called by muse, varscan2
- COL11A2 | c.243C>T p.P81= | Silent (SNP) | VAF 203/605 reads (34%) | called by muse, mutect2, varscan2
- COL22A1 | c.1632C>T p.D544= | Silent (SNP) | VAF 71/391 reads (18%) | catalogued as rs373172764; called by muse, mutect2, varscan2
- COL24A1 | c.3729A>G p.G1243= | Silent (SNP) | VAF 31/148 reads (21%) | called by muse, mutect2, varscan2
- COL28A1 | c.960C>T p.P320= | Silent (SNP) | VAF 29/117 reads (25%) | called by muse, mutect2, varscan2
- COL5A2 | c.2205A>C p.G735= | Silent (SNP) | VAF 82/345 reads (24%) | called by muse, mutect2, varscan2
- CYP1B1 | c.249C>T p.D83= | Silent (SNP) | VAF 142/281 reads (51%) | catalogued as COSV99572680; called by muse, mutect2, varscan2
- DACT3 | c.954C>T p.A318= | Silent (SNP) | VAF 110/143 reads (77%) | called by muse, mutect2, varscan2
- DMD | c.9594T>C p.S3198= | Silent (SNP) | VAF 123/123 reads (100%) | called by muse, mutect2, varscan2
- DNAH1 | c.8550G>A p.Q2850= | Silent (SNP) | VAF 134/278 reads (48%) | called by muse, mutect2, varscan2
- DRC1 | c.1941G>A p.R647= | Silent (SNP) | VAF 54/204 reads (26%) | catalogued as rs761559151; called by muse, mutect2, varscan2
- EGR4 | c.1653G>A p.A551= (on ENST00000545030; = p.A448= on NM_001965.4) | Silent (SNP) | VAF 113/395 reads (29%) | catalogued as COSV71532047; called by muse, mutect2, varscan2
- EMILIN2 | c.1389C>T p.N463= | Silent (SNP) | VAF 140/140 reads (100%) | catalogued as rs1363674860; called by muse, mutect2, varscan2
- ERGIC3 | c.10C>T p.L4= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs780217381; called by muse, mutect2
- ESR1 | c.738C>T p.Y246= | Silent (SNP) | VAF 122/276 reads (44%) | catalogued as rs970273955, COSV52782193, COSV99241207; called by muse, mutect2, varscan2
- FOXC2 | c.1149C>T p.A383= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs1379344558; called by muse, mutect2, varscan2
- GPR61 | c.681C>T p.V227= | Silent (SNP) | VAF 105/210 reads (50%) | called by muse, mutect2, varscan2
- HCN1 | c.939T>C p.G313= | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as rs746190871, COSV100299101; called by muse, mutect2, varscan2
- HTR3E | c.936C>T p.F312= (on ENST00000415389 / NM_001256613.1; = p.F327= on NM_182589.2) | Silent (SNP) | VAF 364/546 reads (67%) | catalogued as rs200034444; called by muse, mutect2, varscan2
- IGFBP1 | c.168C>T p.G56= | Silent (SNP) | VAF 343/718 reads (48%) | called by muse, mutect2, varscan2
- IPO8 | c.267C>G p.R89= | Silent (SNP) | VAF 36/227 reads (16%) | called by muse, mutect2, varscan2
- ITGB7 | c.372G>C p.A124= | Silent (SNP) | VAF 52/157 reads (33%) | called by muse, varscan2
- ITPRIPL2 | c.378C>A p.I126= | Silent (SNP) | VAF 70/180 reads (39%) | called by muse, mutect2, varscan2
- KANSL1L | c.1686A>T p.T562= | Silent (SNP) | VAF 78/287 reads (27%) | called by muse, mutect2, varscan2
- KDM3B | c.177G>A p.V59= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs770495938; called by muse, mutect2, varscan2
- KIF26B | c.2604C>T p.I868= | Silent (SNP) | VAF 115/217 reads (53%) | catalogued as rs375496913; called by muse, mutect2, varscan2
- LRP1B | c.13542T>C p.F4514= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs754357317; called by muse, mutect2, varscan2
- LRP3 | c.1446C>T p.D482= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs200274257; called by muse, mutect2, varscan2
- LSM11 | c.897G>C p.G299= | Silent (SNP) | VAF 66/241 reads (27%) | catalogued as COSV99643901; called by muse, mutect2, varscan2
- MAML1 | c.2817G>A p.G939= | Silent (SNP) | VAF 43/180 reads (24%) | catalogued as rs775764590; called by muse, mutect2, varscan2
- MAPK7 | c.489G>C p.L163= | Silent (SNP) | VAF 64/131 reads (49%) | called by muse, mutect2, varscan2
- MIA2 | c.786T>C p.S262= | Silent (SNP) | VAF 76/131 reads (58%) | called by muse, mutect2, varscan2
- MYLK3 | c.927C>T p.G309= | Silent (SNP) | VAF 44/212 reads (21%) | catalogued as rs752211624; called by muse, mutect2, varscan2
- NCK1 | c.333T>C p.A111= | Silent (SNP) | VAF 38/241 reads (16%) | called by muse, mutect2, varscan2
- NLRP8 | c.1077G>A p.T359= | Silent (SNP) | VAF 80/108 reads (74%) | catalogued as rs1000244011, COSV52587062; called by muse, mutect2, varscan2
- NPBWR1 | c.153T>G p.G51= | Silent (SNP) | VAF 36/416 reads (9%) | called by muse, mutect2
- PAXBP1 | c.135T>A p.G45= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV51608328; called by muse, mutect2, varscan2
- PEG10 | c.966G>A p.P322= (on ENST00000482108 / NM_001040152.2; = p.G356S on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/221 reads (25%) | catalogued as COSV101509847; called by muse, mutect2, varscan2
- PPDPF | c.201C>T p.F67= | Silent (SNP) | VAF 93/850 reads (11%) | called by muse, mutect2, varscan2
- RELN | c.3462C>A p.L1154= | Silent (SNP) | VAF 323/444 reads (73%) | catalogued as COSV58996490, COSV59040219; called by muse, mutect2, varscan2
- RIF1 | c.5526T>C p.D1842= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- RNF213 | c.5181G>A p.T1727= | Silent (SNP) | VAF 44/198 reads (22%) | catalogued as rs1043643434, COSV60411763; called by muse, mutect2, varscan2
- RPS6KA2 | c.1317C>T p.T439= | Silent (SNP) | VAF 40/186 reads (22%) | catalogued as rs1336557047, COSV55821006; called by muse, mutect2, varscan2
- SHOC2 | c.507G>A p.K169= | Silent (SNP) | VAF 58/286 reads (20%) | called by muse, varscan2
- SLC1A2 | c.78G>A p.E26= | Silent (SNP) | VAF 69/145 reads (48%) | called by muse, mutect2, varscan2
- SLFN14 | c.2067T>C p.T689= | Silent (SNP) | VAF 100/381 reads (26%) | called by muse, mutect2, varscan2
- SLITRK6 | c.2475T>C p.A825= | Silent (SNP) | VAF 10/68 reads (15%) | called by mutect2, varscan2
- SMO | c.1416C>T p.Y472= | Silent (SNP) | VAF 33/176 reads (19%) | catalogued as rs766775464, COSV50842459; called by muse, mutect2, varscan2
- SOX17 | c.738G>A p.P246= | Silent (SNP) | VAF 70/287 reads (24%) | catalogued as rs753314063; called by muse, mutect2, varscan2
- STOX2 | c.1284C>T p.N428= | Silent (SNP) | VAF 47/89 reads (53%) | catalogued as rs183419852; called by muse, mutect2, varscan2
- STRN | c.579C>T p.V193= | Silent (SNP) | VAF 69/199 reads (35%) | called by muse, mutect2, varscan2
- TMEM168 | c.987A>G p.V329= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs749060676; called by muse, mutect2, varscan2
- TRIM71 | c.40C>T p.L14= | Silent (SNP) | VAF 58/255 reads (23%) | called by muse, varscan2
- TTN | c.7551G>A p.L2517= (on ENST00000591111; = p.L2471= on NM_003319.4) | Silent (SNP) | VAF 48/191 reads (25%) | called by muse, mutect2, varscan2
- U2SURP | c.898T>C p.L300= | Silent (SNP) | VAF 7/168 reads (4%) | called by muse, mutect2
- USH2A | c.4389A>G p.L1463= | Silent (SNP) | VAF 80/355 reads (23%) | called by muse, mutect2, varscan2
- VPS13A | c.2673G>A p.L891= | Silent (SNP) | VAF 93/305 reads (30%) | called by muse, mutect2, varscan2
- XDH | c.3624C>A p.T1208= | Silent (SNP) | VAF 68/257 reads (26%) | called by muse, mutect2, varscan2
- XKR4 | c.1440T>G p.A480= | Silent (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2
- YEATS2 | c.2817G>A p.S939= | Silent (SNP) | VAF 83/384 reads (22%) | catalogued as rs777936756; called by muse, mutect2, varscan2
- ZBTB8B | c.1317C>A p.P439= | Silent (SNP) | VAF 101/373 reads (27%) | called by muse, mutect2, varscan2
- ZDBF2 | c.597A>T p.P199= | Silent (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- ZNF469 | c.10749G>C p.A3583= (on ENST00000437464; = p.A3611= on NM_001367624.2) | Silent (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- ZNF677 | c.336T>C p.Y112= | Silent (SNP) | VAF 56/172 reads (33%) | called by muse, mutect2, varscan2
- AC009053.1 | chr16:74336675 C>A | 3'Flank (SNP) | VAF 26/430 reads (6%) | called by muse, mutect2
- AFG3L2 | c.-4G>A | 5'UTR (SNP) | VAF 263/264 reads (100%) | called by muse, mutect2, varscan2
- AL353753.1 | n.471A>C | RNA (SNP) | VAF 33/227 reads (15%) | called by muse, mutect2, varscan2
- AMT | c.696+32G>T | Intron (SNP) | VAF 108/448 reads (24%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.708C>A | RNA (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- AVPR2 | chrX:153902712 C>T | 5'Flank (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- BAHCC1 | c.-119C>A | 5'UTR (SNP) | VAF 45/146 reads (31%) | called by muse, mutect2, varscan2
- BRCA2 | c.-8A>T | 5'UTR (SNP) | VAF 44/241 reads (18%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+3244T>G | Intron (SNP) | VAF 16/36 reads (44%) | catalogued as COSV99635227; called by muse, mutect2, varscan2
- CELF4 | c.658-84C>T | Intron (SNP) | VAF 171/172 reads (99%) | catalogued as COSV100612084; called by muse, mutect2, varscan2
- COL4A1 | c.-18C>T | 5'UTR (SNP) | VAF 80/408 reads (20%) | catalogued as rs1222089552; called by muse, mutect2, varscan2
- CORO6 | c.-173G>C | 5'UTR (SNP) | VAF 91/162 reads (56%) | called by muse, mutect2, varscan2
- DSCAML1 | c.*42G>A | 3'UTR (SNP) | VAF 45/231 reads (19%) | catalogued as rs762695017; called by muse, mutect2, varscan2
- EFCAB14 | c.1074+32A>T | Intron (SNP) | VAF 52/267 reads (19%) | called by muse, mutect2, varscan2
- ERICH1 | c.-5C>A | 5'UTR (SNP) | VAF 44/44 reads (100%) | called by muse, mutect2, varscan2
- GATM | chr15:45378564 G>A | 5'Flank (SNP) | VAF 16/24 reads (67%) | called by muse, mutect2, varscan2
- GPX3 | c.87+155C>T | Intron (SNP) | VAF 9/42 reads (21%) | catalogued as rs919485804; called by muse, mutect2, varscan2
- HP | c.5+60A>G | Intron (SNP) | VAF 84/505 reads (17%) | catalogued as rs1452531144, COSV63325746; called by muse, varscan2
- HSPA7 | n.395C>T | RNA (SNP) | VAF 179/369 reads (49%) | called by muse, varscan2
- IGF2BP2 | c.240-23942A>T | Intron (SNP) | VAF 56/453 reads (12%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1172-27194G>C | Intron (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- LINC02817 | n.408C>G | RNA (SNP) | VAF 50/223 reads (22%) | called by muse, mutect2, varscan2
- LRP2 | c.13200-41A>T | Intron (SNP) | VAF 68/305 reads (22%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+3658C>T | Intron (SNP) | VAF 140/269 reads (52%) | catalogued as rs1480392453; called by muse, mutect2, varscan2
- MED13L | c.6501-23G>T | Intron (SNP) | VAF 91/276 reads (33%) | called by muse, mutect2, varscan2
- MFN2 | c.817-22G>A | Intron (SNP) | VAF 114/357 reads (32%) | called by muse, mutect2, varscan2
- MUS81 | c.-49C>T | 5'UTR (SNP) | VAF 64/292 reads (22%) | called by muse, mutect2, varscan2
- NDRG4 | c.37+11176C>A | Intron (SNP) | VAF 18/171 reads (11%) | called by muse, mutect2, varscan2
- NSMF | c.-5C>A | 5'UTR (SNP) | VAF 64/79 reads (81%) | called by muse, mutect2, varscan2
- PHACTR2 | c.14-33921G>C | Intron (SNP) | VAF 56/231 reads (24%) | catalogued as COSV99991280; called by muse, mutect2, varscan2
- PPIA | c.-22G>T | 5'UTR (SNP) | VAF 55/396 reads (14%) | called by muse, mutect2, varscan2
- RFT1 | c.1102+47_1102+49del | Intron (DEL) | VAF 41/190 reads (22%) | called by mutect2, pindel, varscan2
- RN7SL495P | chr15:22611773 T>A | 5'Flank (SNP) | VAF 63/241 reads (26%) | called by muse, mutect2, varscan2
- RPS3 | chr11:75405638 G>A | 3'Flank (SNP) | VAF 26/320 reads (8%) | called by muse, mutect2
- S100A11 | c.-22C>G | 5'UTR (SNP) | VAF 35/146 reads (24%) | called by muse, mutect2, varscan2
- SBF1 | c.-141C>T | 5'UTR (SNP) | VAF 18/84 reads (21%) | catalogued as rs1460204952; called by muse, mutect2, varscan2
- SCARF2 | c.*43C>T | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- SERPINB11 | c.618+37G>T | Intron (SNP) | VAF 59/59 reads (100%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.191C>T | RNA (SNP) | VAF 45/254 reads (18%) | catalogued as rs1175038660; called by muse, mutect2, varscan2
- SSB | c.345+176C>T | Intron (SNP) | VAF 29/79 reads (37%) | catalogued as rs1167392178; called by muse, mutect2, varscan2
- STRA8 | c.420-9T>G | Intron (SNP) | VAF 55/122 reads (45%) | called by muse, mutect2, varscan2
- STX3 | c.-88C>T | 5'UTR (SNP) | VAF 65/255 reads (25%) | called by muse, mutect2, varscan2
- TRIM6 | c.-68+629T>G | Intron (SNP) | VAF 91/178 reads (51%) | called by muse, mutect2, varscan2
- TTYH1 | c.126+1147G>A | Intron (SNP) | VAF 340/449 reads (76%) | called by muse, mutect2, varscan2
- TUBA1B | c.4-663A>G | Intron (SNP) | VAF 38/190 reads (20%) | called by muse, varscan2
- TXNDC9 | c.309-461C>A | Intron (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- UMODL1 | c.1900-58G>A | Intron (SNP) | VAF 138/277 reads (50%) | called by muse, mutect2, varscan2
